Gene-level copy-number profile of tumor specimen HCM-SANG-0270-C20-86A from HCMI case HCM-SANG-0270-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0270-C20-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file afd21a26-13d7-49bb-90f0-2e0fbadded83.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0270-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/ff81c47f-4f7c-4d14-9314-e4ddee4009c4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 76; copy number 2: 54,450; copy number 3: 3,511; copy number 4: 355; copy number 6: 1; copy number 15: 1; copy number 16: 2; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,552,713–32,668,383, 5 genes, copy number 6–17: HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1.

Autosomal genes at a single copy (total copy number 1): 69. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
